Gene-level copy-number profile of tumor specimen TCGA-Z2-AA3S-06A from TCGA case TCGA-Z2-AA3S, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.6 years (23,946 days).
Specimen TCGA-Z2-AA3S-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.4afffc7f-8424-4810-914d-595ac609abaa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Z2-AA3S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b280bdaf-b503-440f-9e55-1f0d1e5d7ad9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 13,525; copy number 2: 42,165; copy number 3: 2,361; copy number 4: 1,732; copy number 5: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Z2-AA3S-06A-11D-A396-01): tumor purity 0.91, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:32,685,145–32,786,116, 4 genes: CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43.
- chr9:21,929,457–22,128,103, 9 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:87,659,613–87,863,533, 5 genes (within-gene range 0–1): PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr10:87,878,692–87,880,427, 1 gene: AC063965.2.
- chr10:116,849,499–116,911,788, 1 gene: ENO4.
- chr11:80,751,200–81,040,236, 3 genes: LINC02720, AP003398.1, AP003398.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:78,597,239–79,767,998, 5 genes, copy number 5 (within-gene range 2–5): ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923.
- chr3:83,384,445–83,437,728, 1 gene, copy number 5: AC023503.1.

Autosomal genes at a single copy (total copy number 1): 11,143. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
